Gene-level copy-number profile of tumor specimen ALCH-B1VT-TTP1-A from ALCHEMIST case ALCH-B1VT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 59.1 years (21,576 days).
Specimen ALCH-B1VT-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5aab4f67-cb5b-4ce3-8ac8-68d8b06d2411.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/c1dc4636-6130-497e-8d81-bb21a8ff9100

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 5,247; copy number 2: 52,592; copy number 3: 908; copy number 4: 66; copy number 5: 7; copy number 6: 3; copy number 7: 5; copy number 8: 24; copy number 9: 1; copy number 10: 2; copy number 11: 1; copy number 12: 2; copy number 14: 2; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,922,554–12,928,253, 2 genes (within-gene range 0–2): RNU6-1072P, PRAMEF29P.
- chr1:13,163,914–13,371,900, 14 genes: HNRNPCL4, PRAMEF9, PRAMEF13, PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19.
- chr2:15,801,747–15,810,877, 1 gene: AC113608.1.
- chr5:171,419,647–171,457,626, 2 genes: FGF18, AC093246.1.
- chr9:136,726,104–136,726,879, 4 genes (within-gene range 0–1): SNORA17B, SNORA17B, SNORA17A, AL355987.6.
- chr14:24,171,853–24,180,257, 1 gene (within-gene range 0–1): REC8.
- chr14:106,874,583–106,879,812, 2 genes: IGHV7-81, IGHVIII-82.
- chr22:18,527,802–18,653,617, 9 genes: TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 48 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,402,932–1,406,442, 1 gene, copy number 10: NKX1-1.
- chr8:35,235,475–35,796,550, 4 genes, copy number 7: UNC5D, AC090740.1, LSM12P1, AC105230.1.
- chr8:38,269,704–38,382,272, 1 gene, copy number 8 (within-gene range 3–8): NSD3.
- chr8:38,335,981–39,284,917, 23 genes, copy number 8: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10.
- chr9:136,546,173–136,687,457, 7 genes, copy number 5–7 (within-gene range 5–22): MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2.
- chr9:136,754,386–136,766,255, 2 genes, copy number 9–10: LCN8, LCN15.
- chr9:136,848,724–136,860,799, 2 genes, copy number 14 (within-gene range 2–14): PHPT1, MAMDC4.
- chr14:105,583,731–105,588,395, 1 gene, copy number 12: IGHA2.
- chr14:105,620,506–105,626,066, 2 genes, copy number 6–12: IGHG4, MIR8071-1.
- chr16:848,525–849,065, 1 gene, copy number 16: AL031008.1.
- chr16:88,382,959–88,537,031, 2 genes, copy number 5–6 (within-gene range 3–13): ZNF469, ZFPM1.
- chr16:88,512,960–88,531,053, 1 gene, copy number 6 (within-gene range 6–13): AC116552.1.
- chr22:18,715,815–18,719,341, 1 gene, copy number 11: PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 2,409. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
